Somatic mutation profile of tumor specimen 1105229 (aliquot 7316UP-243-1105229) from CPTAC case C247230, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G4.
Specimen 1105229: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed961b3-ef06-4717-8500-81aff35b6b71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105280 (Blood Derived Normal), aliquot 7316UP-243-1105280; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c142fc6-ef1b-4a9e-b5e3-6af8325d5eb0

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D4 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs775588255; ClinVar: uncertain significance; called by muse, mutect2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2
- GBA | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs748485792, CM140309, COSV59169558; called by muse, mutect2
- SHROOM4 | c.4019A>G p.N1340S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1055639018; called by muse, mutect2
- GIGYF2 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- HPCAL1 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- ARSH | c.321C>T p.G107= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- OR2T10 | c.313C>T p.L105= | Silent (SNP) | VAF 15/218 reads (7%) | catalogued as COSV57897015, COSV57897073; called by muse, mutect2
- PDZD7 | c.2139G>C p.G713= | Silent (SNP) | VAF 7/199 reads (4%) | called by muse, mutect2
- TMEM147 | c.481C>T p.L161= | Silent (SNP) | VAF 10/340 reads (3%) | called by muse, mutect2
- ANKRD18A | chr9:38621264 G>C | 5'Flank (SNP) | VAF 15/391 reads (4%) | catalogued as rs1457530152; called by muse, mutect2
- LGI4 | c.1300-233C>T | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- PNPLA7 | c.1151-3595G>C | Intron (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
